PECGS case C083-000005 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/f63993f9-af6b-413a-9916-65b4c9837519

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 68 years; Year of birth: 1954; Education level: Some High School or Less.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Age at diagnosis: 68.3 years (24,947 days); AJCC pathologic stage: Stage IIA; Progression or recurrence: yes; Days to last follow up: 370 days (1.0 years).

Other clinical attributes
- BMI: 26.26.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 41.25; Alcohol history: No.

Biospecimens (2 samples)
- Sample C083-000005_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000005_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
